CCDI case PBBZYA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/36ace27d-52f6-4e00-a981-0da2de672494

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 18.0 years (6,580 days).

Biospecimens (3 samples)
- Sample 0DLX4Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX5A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLX5L: Tissue type: Tumor; Specimen type: Solid Tissue.
